Gene-level copy-number profile of tumor specimen ALCH-ADYW-TTP1-A from ALCHEMIST case ALCH-ADYW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,912 days).
Specimen ALCH-ADYW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a1e7f9d1-a0d0-4702-b3da-9fd55a8556dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADYW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ce2bf305-befd-4da4-bb17-18b1dd3aaebb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,126; copy number 2: 50,734; copy number 3: 1,662; copy number 4: 653; copy number 5: 25; copy number 6: 36; copy number 7: 83; copy number 8: 12; copy number 12: 1; copy number 20: 4; copy number 21: 12; copy number 26: 49.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:3,441,968–3,449,486, 1 gene: HGFAC.
- chr17:2,366,589–2,366,791, 1 gene (within-gene range 0–2): AC006435.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–35,796,550, 1 gene, copy number 8 (within-gene range 2–8): UNC5D.
- chr8:35,525,176–36,779,209, 13 genes, copy number 5–8 (within-gene range 4–8): LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10.
- chr11:77,313,606–78,444,049, 36 genes, copy number 6 (within-gene range 3–6): TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr12:66,950,754–69,579,793, 61 genes, copy number 21–26 (broad region; genes not listed).
- chr12:78,326,680–80,029,631, 22 genes, copy number 5: LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38.
- chr14:33,924,227–37,552,361, 84 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,856. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
